Gene-level copy-number profile of tumor specimen TARGET-40-PAKXLD-01A from TARGET case TARGET-40-PAKXLD, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 14.4 years (5,245 days).
Specimen TARGET-40-PAKXLD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.f9edfd72-4614-52b6-94b2-504d96f8ce71.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAKXLD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 367 have no estimate.
https://portal.gdc.cancer.gov/files/43e9301a-c5e3-4021-bb7b-6a3de976997e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 723; copy number 1: 1,170; copy number 2: 15,609; copy number 3: 16,568; copy number 4: 20,447; copy number 5: 2,569; copy number 6: 1,540; copy number 7: 403; copy number 8: 325; copy number 9: 133; copy number 10: 173; copy number 11: 23; copy number 12: 283; copy number 13: 88; copy number 14: 111; copy number 15: 11; copy number 17: 17; copy number 18: 31; copy number 19: 5; copy number 20: 1; copy number 21: 2; copy number 24: 13; copy number 25: 9; copy number 38: 1; copy number 40: 1.

Homozygous deletions (total copy number 0; autosomes only): 203 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,552,473–117,027,039, 10 genes: LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr11:120,511,746–120,988,906, 1 gene (within-gene range 0–5): GRIK4.
- chr11:120,867,933–127,337,033, 192 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 902 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:190,880,797–191,847,088, 19 genes, copy number 10: AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P, NABP1, AC114778.1, NABP1-OT1, AC098872.1, CAVIN2.
- chr3:857,124–1,012,934, 2 genes, copy number 10: AC090044.1, AC087430.1.
- chr3:3,126,933–3,627,296, 4 genes, copy number 9–11 (within-gene range 4–11): TRNT1, CRBN, AC024060.2, AC034195.1.
- chr3:3,799,431–4,046,722, 3 genes, copy number 11: LRRN1, AC023480.1, PNPT1P1.
- chr3:18,345,377–18,955,049, 5 genes, copy number 13: SATB1, AC144521.1, SATB1-AS1, RAD23BP1, RNU6-138P.
- chr3:20,174,244–21,145,967, 1 gene, copy number 10 (within-gene range 7–12): SGO1-AS1.
- chr3:21,006,730–22,373,321, 4 genes, copy number 10 (within-gene range 4–12): AC099753.1, VENTXP7, ZNF385D, ZNF385D-AS1.
- chr3:22,811,390–23,591,794, 8 genes, copy number 9–13 (within-gene range 2–13): AC114477.1, RANP7, SALL4P5, RPL24P7, UBE2E2-AS1, UBE2E2, Y_RNA, AC121251.1.
- chr3:30,606,601–30,694,142, 1 gene, copy number 10 (within-gene range 4–10): TGFBR2.
- chr3:30,697,661–31,637,616, 8 genes, copy number 10: AC096921.2, GADL1, MIR466, CNN2P6, RNA5SP127, H3P11, THRAP3P1, STT3B.
- chr3:31,704,058–31,721,652, 1 gene, copy number 10 (within-gene range 8–10): OSBPL10-AS1.
- chr3:33,554,636–33,554,859, 1 gene, copy number 15: COX6CP10.
- chr6:122,211,648–122,211,811, 1 gene, copy number 38: RNU1-18P.
- chr7:83,955,777–84,584,322, 2 genes, copy number 9–10 (within-gene range 6–10): SEMA3A, AC003984.1.
- chr11:90,251,204–90,915,052, 1 gene, copy number 13 (within-gene range 8–13): DISC1FP1.
- chr11:90,555,774–95,497,553, 105 genes, copy number 12–13 (broad region; genes not listed).
- chr11:95,963,219–95,963,624, 1 gene, copy number 20: AP000870.1.
- chr11:96,341,438–110,296,712, 170 genes, copy number 12–14 (within-gene range 3–14) (broad region; genes not listed).
- chr11:117,800,844–117,929,459, 6 genes, copy number 11: FXYD2, AP000757.2, FXYD6-FXYD2, AP000757.1, FXYD6, TMPRSS13.
- chr11:118,193,725–119,025,454, 53 genes, copy number 12–19 (within-gene range 5–19): JAML, HSPE1P18, MPZL3, MPZL2, AP002800.1, CD3E, AP001582.1, CD3D, CD3G, UBE4A, AP001267.1, AP001267.5, ATP5MG, AP001267.4, AP001267.2, KMT2A, AP001267.3, TTC36, TMEM25, IFT46, RPL5P30, ARCN1, PHLDB1, AP000941.1, MIR6716, TREH, TREHP1, AP002954.1, RNU6-376P, AP002954.2, DDX6, AP004609.3, AP004609.2, SETP16, Y_RNA, CXCR5, AP004609.1, BCL9L, MIR4492, UPK2, RN7SL688P, Y_RNA, FOXR1, Metazoa_SRP, Y_RNA, CENATAC-DT, CENATAC, RPL23AP64, AP003392.1, AP003392.2, RPS25, TRAPPC4, AP003392.15.
- chr17:9,764,186–11,564,063, 43 genes, copy number 10–13 (within-gene range 8–13): AC027045.2, DHRS7C, AC027045.1, GSG1L2, AC027045.3, GLP2R, NPM1P45, RCVRN, GAS7, RPS27AP1, AC005291.2, MYH13, AC005291.1, AC005323.2, MYHAS, MYH8, MYH4, MYH1, MYH2, AC005323.1, MYH3, AC002347.1, SCO1, AC002347.2, ADPRM, TMEM220, MAGOH2P, TMEM220-AS1, AC015908.7, AC015908.3, AC015908.1, AC015908.4, AC015908.6, TMEM238L, AC015908.5, PIRT, AC015908.2, RNU6-1065P, RPL15P21, RN7SL601P, AC005548.1, SHISA6, AC005725.1.
- chr17:12,917,268–12,917,342, 1 gene, copy number 14: MIR1269B.
- chr17:13,494,032–16,934,839, 119 genes, copy number 9–24 (broad region; genes not listed).
- chr17:19,737,984–22,529,570, 118 genes, copy number 10–12 (broad region; genes not listed).
- chr19:27,793,431–27,984,984, 1 gene, copy number 9 (within-gene range 5–9): AC006504.5.
- chr19:27,849,635–32,485,895, 82 genes, copy number 9–40 (broad region; genes not listed).
- chr19:34,126,973–35,353,862, 67 genes, copy number 9–11 (broad region; genes not listed).
- chr20:48,324,812–51,098,845, 75 genes, copy number 9–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,170. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
